Somatic mutation profile of tumor specimen 0DPU55 from CCDI case PBCEDN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.9 years (5,424 days).
Specimen 0DPU55: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34c9b1cb-1043-421f-819d-e0104a481590.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPU54 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5e4327a-b876-4c98-a742-68ec19c15a55

The open-access MAF lists 67 somatic variants for this specimen: 56 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 7, Nonsense Mutation 5, Splice Region 4, 3'UTR 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 248/572 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, varscan2
- ANK2 | c.1646T>C p.L549P | Missense Mutation (SNP) | VAF 245/742 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs537148509; called by muse, varscan2
- CACNA1E | c.5986G>T p.G1996W | Missense Mutation (SNP) | VAF 197/461 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV62429348; called by muse, varscan2
- CAPN7 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 152/472 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.227); catalogued as rs201136378; called by muse, varscan2
- COL7A1 | c.4979G>A p.R1660Q | Missense Mutation (SNP) | VAF 158/343 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as rs373152375; called by muse, varscan2
- DNAH11 | c.4126G>A p.V1376I | Missense Mutation (SNP) | VAF 168/414 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs531283952, COSV60938522, COSV60977719; called by muse, varscan2
- FAM217B | c.878A>C p.K293T | Missense Mutation (SNP) | VAF 56/468 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs1303903947; called by muse, varscan2
- FCN3 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 169/390 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1018094906, COSV54641096; called by muse, varscan2
- FLI1 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 124/333 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1411030692; called by muse, varscan2
- HSPG2 | c.7244C>T p.P2415L | Missense Mutation (SNP) | VAF 133/290 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs1185405772; called by muse, varscan2
- INTS4 | c.628C>G p.R210G | Missense Mutation (SNP) | VAF 274/580 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs759046434, COSV71088633; called by muse, varscan2
- ITIH6 | c.478C>A p.Q160K | Missense Mutation (SNP) | VAF 194/204 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV54494838; called by muse, varscan2
- LDAH | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 76/761 reads (10%) | catalogued as rs1466230012; called by muse, varscan2
- LRIG3 | c.3264G>C p.R1088S | Missense Mutation (SNP) | VAF 92/873 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); catalogued as COSV100292925; called by muse, varscan2
- MECOM | c.2194C>G p.R732G (on ENST00000468789 / NM_001105078.4; = p.R920G on NM_004991.4) | Missense Mutation (SNP) | VAF 236/717 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV99245859; called by muse, varscan2
- MYH2 | c.4194G>T p.K1398N | Missense Mutation (SNP) | VAF 103/303 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55442437; called by muse, varscan2
- NBEAL1 | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 227/529 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs992581636; called by muse, varscan2
- NPC1 | c.3713C>A p.T1238N | Missense Mutation (SNP) | VAF 220/500 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV52574117; called by muse, varscan2
- OFD1 | c.494C>A p.S165* | Nonsense Mutation (SNP) | VAF 172/304 reads (57%) | catalogued as COSV60795323; called by muse, varscan2
- PHF5A | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 231/484 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV53439599; called by muse, varscan2
- PPP4R1 | c.186C>T p.N62= (on ENST00000400556 / NM_001042388.3; = p.N45= on NM_005134.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 210/418 reads (50%) | catalogued as rs1417951631; called by muse, varscan2
- RAC1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 98/346 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV61821605; called by muse, varscan2
- RALGAPA1 | c.1789C>G p.P597A | Missense Mutation (SNP) | VAF 266/788 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV51888683; called by muse, varscan2
- SNX9 | c.99G>A p.P33= | Splice Region (SNP) | VAF 295/691 reads (43%) | catalogued as rs145589455; called by muse, varscan2
- SSBP4 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 86/443 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.44); catalogued as rs192982931; called by muse, varscan2
- ZNF616 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765934151, COSV57509360; called by muse, varscan2
- ZSWIM8 | c.5258G>A p.R1753H (on ENST00000605216 / NM_001242487.2; = p.R1758H on NM_015037.3) | Missense Mutation (SNP) | VAF 95/188 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1266972200; called by muse, varscan2
- ABCB4 | c.3522A>T p.R1174S (on ENST00000265723 / NM_018849.3; = p.R1167S on NM_000443.4) | Missense Mutation (SNP) | VAF 127/371 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.426); called by muse, varscan2
- ACTB | c.487G>C p.V163L | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- ARID3A | c.1197A>G p.K399= | Splice Region (SNP) | VAF 144/348 reads (41%) | called by muse, varscan2
- BNC2 | c.2004T>G p.N668K | Missense Mutation (SNP) | VAF 158/471 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, varscan2
- BSN | c.10864G>A p.E3622K | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, varscan2
- CADPS2 | c.2476G>T p.E826* | Nonsense Mutation (SNP) | VAF 95/803 reads (12%) | called by muse, varscan2
- CP | c.114C>A p.D38E | Missense Mutation (SNP) | VAF 190/612 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, varscan2
- DCAF6 | c.1523G>A p.G508E (on ENST00000312263 / NM_001349778.1; = p.G528E on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/614 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); called by muse, varscan2
- DNHD1 | c.11212G>A p.G3738S | Missense Mutation (SNP) | VAF 206/449 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, varscan2
- GJA8 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 202/458 reads (44%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.996); called by muse, varscan2
- HECW2 | c.2838C>A p.N946K | Missense Mutation (SNP) | VAF 225/654 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, varscan2
- HIPK2 | c.2285A>G p.N762S | Missense Mutation (SNP) | VAF 160/386 reads (41%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.952); called by muse, varscan2
- HSCB | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 114/429 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, varscan2
- HSD3B2 | c.209G>T p.R70I | Missense Mutation (SNP) | VAF 242/616 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); called by muse, varscan2
- IL31RA | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 128/330 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, varscan2
- MYH3 | c.5048A>G p.Q1683R | Missense Mutation (SNP) | VAF 172/358 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.158); called by muse, varscan2
- OR51A4 | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 267/678 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, varscan2
- OSBP | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 58/487 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, varscan2
- RBBP7 | c.122G>A p.W41* | Nonsense Mutation (SNP) | VAF 240/356 reads (67%) | called by muse, varscan2
- SMARCD1 | c.1487A>C p.Y496S | Missense Mutation (SNP) | VAF 139/318 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); called by muse, varscan2
- SMTN | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 118/287 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.058); called by muse, varscan2
- SPTBN4 | c.714C>A p.N238K | Missense Mutation (SNP) | VAF 87/558 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.438); called by muse, varscan2
- ST18 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 38/336 reads (11%) | called by muse, varscan2
- STEAP2 | c.1047G>T p.W349C | Missense Mutation (SNP) | VAF 290/688 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- TBX15 | c.1385T>C p.M462T (on ENST00000369429 / NM_001330677.2; = p.M356T on NM_152380.3) | Missense Mutation (SNP) | VAF 124/274 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.428); called by muse, varscan2
- WDR55 | c.1115A>T p.Q372L | Missense Mutation (SNP) | VAF 55/432 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, varscan2
- WEE2 | c.1029T>C p.S343= | Splice Region (SNP) | VAF 328/744 reads (44%) | called by muse, varscan2
- WNT2 | c.1072A>T p.T358S | Missense Mutation (SNP) | VAF 86/250 reads (34%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, varscan2
- ZNF516 | c.2162G>T p.G721V | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, varscan2
- BBS9 | c.1761A>G p.R587= (on ENST00000242067 / NM_001348036.1; = p.R547= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 326/722 reads (45%) | called by muse, varscan2
- CACNG3 | c.354C>T p.G118= | Silent (SNP) | VAF 148/348 reads (43%) | catalogued as rs546224102, COSV50084811; called by muse, varscan2
- FTHL17 | c.372G>A p.E124= | Silent (SNP) | VAF 154/202 reads (76%) | catalogued as rs754539351; called by muse, varscan2
- HDAC4 | c.1767C>T p.L589= | Silent (SNP) | VAF 74/232 reads (32%) | called by muse, varscan2
- LTBP2 | c.1536G>A p.P512= | Silent (SNP) | VAF 68/132 reads (52%) | catalogued as rs371191837; called by muse, varscan2
- MUC12 | c.3993C>G p.T1331= (on ENST00000379442; = p.T1188= on NM_001164462.1) | Silent (SNP) | VAF 52/142 reads (37%) | called by muse, varscan2
- TADA3 | c.420C>T p.I140= | Silent (SNP) | VAF 52/496 reads (10%) | catalogued as rs760618790, COSV55029673; called by muse, varscan2
- AC021218.1 | n.444G>A | RNA (SNP) | VAF 111/228 reads (49%) | catalogued as rs531573166; called by muse, varscan2
- GJD4 | c.64+47A>T | Intron (SNP) | VAF 55/108 reads (51%) | called by muse, varscan2
- LARP1 | c.*62G>C | 3'UTR (SNP) | VAF 50/130 reads (38%) | called by muse, varscan2
- OSCAR | c.*419C>T | 3'UTR (SNP) | VAF 89/392 reads (23%) | catalogued as rs148850642; called by muse, varscan2
